Somatic mutation profile of tumor specimen TCGA-F7-A622-01A (aliquot TCGA-F7-A622-01A-11D-A28R-08) from TCGA case TCGA-F7-A622, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 75.2 years (27,456 days).
Specimen TCGA-F7-A622-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdcf092b-1504-4fe1-8e49-545cf65e1b40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F7-A622-10A (Blood Derived Normal), aliquot TCGA-F7-A622-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6372f7d2-d371-4862-bc40-4899b562fa82

The open-access MAF lists 70 somatic variants for this specimen: 52 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 17, Frame Shift Del 6, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1, In Frame Ins 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TGFBR2 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104893810, CM050761, CM140638, COSV55443375, COSV55461069, COSV99848566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.853A>G p.M285V | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV100383137; called by muse, mutect2, varscan2
- ADHFE1 | c.635C>G p.T212S | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV99397875; called by muse, mutect2, varscan2
- ANO9 | c.2051G>A p.R684H | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs373327405, COSV60385509; called by muse, mutect2, varscan2
- ARHGAP39 | c.2911C>T p.R971W (on ENST00000276826 / NM_001308208.2; = p.R1002W on NM_025251.2) | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV52769023; called by muse, mutect2, varscan2
- BTBD7 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs374507319; called by muse, mutect2, varscan2
- CCDC7 | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV99511624; called by muse, mutect2, varscan2
- CES4A | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as rs202172028; called by muse, mutect2, varscan2
- CFAP299 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs142731425; called by muse, mutect2, varscan2
- COL1A1 | c.2443G>T p.G815C | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99867301; called by muse, mutect2, varscan2
- CXXC1 | c.1863del p.N621Kfs*6 | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | catalogued as COSV53275569; called by mutect2, pindel, varscan2
- DAB2IP | c.2323C>T p.Q775* (on ENST00000408936; = p.Q747* on NM_032552.3) | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as COSV99405575; called by muse, mutect2, varscan2
- DDB1 | c.3042G>T p.M1014I | Missense Mutation (SNP) | VAF 163/295 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV100074617, COSV57104378; called by muse, mutect2, varscan2
- DNAH3 | c.348G>T p.L116F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.168); catalogued as COSV99767730; called by muse, mutect2
- DNAJB11 | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.895); catalogued as rs1446240668, COSV54003517; called by muse, mutect2
- FAM193A | c.125G>C p.C42S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100219248; called by muse, mutect2, varscan2
- FANCF | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs587778341, COSV59417664; ClinVar: not provided; called by muse, mutect2, varscan2
- FAR1 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.029); catalogued as rs781245757, COSV100701582; called by muse, mutect2, varscan2
- FAT3 | c.6905T>C p.I2302T | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53126027; called by muse, mutect2, varscan2
- FEM1A | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99521456; called by muse, mutect2, varscan2
- FOXR1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs782742201, COSV100392919; called by muse, mutect2, varscan2
- GPR68 | c.32T>C p.M11T | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99473480; called by muse, mutect2, varscan2
- GUCY2C | c.1013T>C p.I338T | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1565630544, COSV99663687; called by muse, mutect2, varscan2
- HMCN1 | c.14491G>A p.G4831R | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774478146, COSV99629751; called by muse, mutect2, varscan2
- KSR2 | c.2024G>A p.G675D | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100195310, COSV99043554; called by muse, mutect2, varscan2
- LYST | c.2882C>G p.A961G | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV101089577; called by muse, mutect2, varscan2
- MMP16 | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as COSV99688476; called by muse, mutect2, varscan2
- MSH6 | c.942C>G p.S314R | Missense Mutation (SNP) | VAF 89/323 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs150440246; ClinVar: likely benign / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- NDE1 | c.18G>C p.K6N | Missense Mutation (SNP) | VAF 35/230 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as COSV100707114; called by muse, mutect2, varscan2
- NDUFB1 | c.-3A>G | Splice Region (SNP) | VAF 16/45 reads (36%) | catalogued as rs780594896, COSV100102887; called by muse, mutect2, varscan2
- NOTCH1 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300110216, COSV53032942; called by muse, mutect2, varscan2
- NOX5 | c.2196G>C p.K732N | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV52995899, COSV99533916; called by muse, mutect2, varscan2
- OR4N2 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 54/236 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100269632; called by muse, mutect2, varscan2
- PCDHB8 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 27/539 reads (5%) | catalogued as COSV99176999; called by muse, mutect2
- PRICKLE3 | c.1438C>A p.L480M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.832); catalogued as COSV100889921; called by mutect2, varscan2
- RASGRF1 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 50/69 reads (72%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as rs200752675, COSV69181378; called by muse, mutect2, varscan2
- REST | c.814C>A p.P272T | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100471020, COSV58360706; called by muse, mutect2, varscan2
- SHPRH | c.758T>C p.I253T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as COSV99262140; called by mutect2, varscan2
- SUPT16H | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99359897; called by muse, mutect2, varscan2
- TTC5 | c.206A>T p.Q69L | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99351831; called by muse, mutect2, varscan2
- WDR33 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs181571193, COSV100460133; called by muse, mutect2, varscan2
- ZNF468 | c.1515T>A p.S505R | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as COSV99700592; called by muse, mutect2, varscan2
- ZSCAN5A | c.706A>T p.T236S | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as rs770303549, COSV99570218; called by muse, mutect2, varscan2
- ANKRD44 | c.1880_1881del p.F627Cfs*17 | Frame Shift Del (DEL) | VAF 44/193 reads (23%) | called by mutect2, pindel, varscan2
- CHEK2 | c.1622_1656del p.L541Pfs*9 (on ENST00000382580 / NM_001005735.2; = p.L498Pfs*9 on NM_007194.4) | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- ECEL1 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- FAT1 | c.819dup p.A274Cfs*7 | Frame Shift Ins (INS) | VAF 169/347 reads (49%) | called by mutect2, pindel, varscan2
- FBXW7 | c.1252_1261del p.V418Qfs*9 (on ENST00000281708 / NM_001349798.2; = p.V338Qfs*9 on NM_018315.5) | Frame Shift Del (DEL) | VAF 76/129 reads (59%) | called by mutect2, pindel, varscan2
- KMT2D | c.1945_1960del p.E649Pfs*276 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- MYH9 | c.5232_5261del p.N1744_K1753del | In Frame Del (DEL) | VAF 3/36 reads (8%) | called by mutect2, pindel
- PLEKHG6 | c.1834_1836dup p.A612dup | In Frame Ins (INS) | VAF 74/228 reads (32%) | called by mutect2, pindel, varscan2
- SPTBN2 | c.304del p.I102Yfs*47 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- ADH5 | c.576C>T p.G192= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV99596259; called by muse, mutect2, varscan2
- BCHE | c.819C>T p.N273= | Silent (SNP) | VAF 67/121 reads (55%) | catalogued as COSV100012579; called by muse, mutect2, varscan2
- CDC37L1 | c.744C>T p.A248= | Silent (SNP) | VAF 34/55 reads (62%) | catalogued as COSV101116587; called by muse, mutect2, varscan2
- CFAP54 | c.5761T>C p.L1921= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as rs757197063, COSV100733186; called by muse, mutect2, varscan2
- COLEC11 | c.582G>T p.A194= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs374212450, COSV99363288; called by muse, mutect2, varscan2
- DNAH17 | c.7698C>T p.Y2566= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as rs192616101; called by muse, mutect2, varscan2
- DSCAML1 | c.1305G>A p.S435= (on ENST00000321322; = p.S375= on NM_020693.4) | Silent (SNP) | VAF 70/298 reads (23%) | catalogued as rs147591517; called by muse, mutect2, varscan2
- FRY | c.6348G>T p.L2116= | Silent (SNP) | VAF 45/136 reads (33%) | catalogued as COSV100969323; called by muse, mutect2, varscan2
- GPR156 | c.1134C>T p.N378= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs767458987, COSV100251398; called by muse, mutect2, varscan2
- HTR3C | c.978C>T p.T326= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as rs751045506, COSV59177239; called by muse, mutect2, varscan2
- IGFN1 | c.3312C>T p.I1104= (on ENST00000295591 / NM_001367841.1; = p.I3561= on NM_001164586.2) | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV99812487; called by muse, mutect2, varscan2
- IGKV1D-13 | c.258C>A p.G86= | Silent (SNP) | VAF 22/62 reads (35%) | called by mutect2, varscan2
- MCTP2 | c.267C>T p.P89= | Silent (SNP) | VAF 94/119 reads (79%) | catalogued as COSV100537491; called by muse, mutect2, varscan2
- PDGFRB | c.1593G>A p.K531= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as rs757308336, COSV99940643; called by muse, mutect2, varscan2
- RHO | c.789C>T p.I263= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV56212980, COSV99960591, COSV99960640; called by muse, mutect2, varscan2
- RIMS3 | c.42C>T p.S14= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV101013419; called by muse, mutect2, varscan2
- SPATS1 | c.738G>A p.E246= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99913387; called by muse, mutect2, varscan2
- IGKV1-13 | n.259C>A | RNA (SNP) | VAF 36/266 reads (14%) | called by muse, mutect2
